Somatic mutation profile of tumor specimen TARGET-10-PAPBCK-09A (aliquot TARGET-10-PAPBCK-09A-01D) from TARGET case TARGET-10-PAPBCK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,088 days).
Specimen TARGET-10-PAPBCK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0068cc79-f674-4ee9-9b5a-52dccc407ae2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPBCK-10A (Blood Derived Normal), aliquot TARGET-10-PAPBCK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d82ff7d2-9096-4779-b219-54c3a9e04831

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 28/84 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CSMD1 | c.8830C>T p.R2944C (on ENST00000520002; = p.R2943C on NM_033225.6) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1431976322, COSV59318142; called by muse, mutect2, varscan2
- SPEG | c.2671C>T p.R891C | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs868493086; called by muse, mutect2, varscan2
- TNFRSF25 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as rs577486076; called by muse, mutect2, varscan2
- CREBBP | c.5499C>A p.C1833* | Nonsense Mutation (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- GLP1R | c.801G>A p.R267= | Silent (SNP) | VAF 46/120 reads (38%) | called by muse, mutect2, varscan2
- ADAM7 | c.2209-1367A>G | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
